Somatic mutation profile of tumor specimen TARGET-20-PARBEL-09A (aliquot TARGET-20-PARBEL-09A-01D) from TARGET case TARGET-20-PARBEL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.4 years (6,731 days).
Specimen TARGET-20-PARBEL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 846403dd-84ae-41e5-9bcf-18e9d9c4b661.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARBEL-14A (Bone Marrow Normal), aliquot TARGET-20-PARBEL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62704458-f0b4-44c3-b274-1319f903bf97

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2C | c.14073C>G p.Y4691* | Nonsense Mutation (SNP) | VAF 62/431 reads (14%) | catalogued as CM124615, COSV51474151; called by muse, mutect2, varscan2
- CEBPA | c.125_134del p.P42Hfs*115 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, varscan2
- CPM | c.*3101G>C | 3'UTR (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
